Somatic mutation profile of tumor specimen C3L-02542-03 (aliquot CPT0161730006) from CPTAC case C3L-02542, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,544 days).
Specimen C3L-02542-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193124bb-29a6-4dc5-af22-b227e0ace222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02542-31 (Blood Derived Normal), aliquot CPT0162540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9b596ff-d676-44c7-98ba-3bda9404f703

The open-access MAF lists 189 somatic variants for this specimen: 122 protein-altering or splice-affecting, 47 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 47, Intron 14, Nonsense Mutation 7, Splice Region 4, Splice Site 3, 3'UTR 2, RNA 2, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 56/129 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TMEM240 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs606231455, CM148749, COSV59235425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGFG2 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as COSV53544193; called by muse, mutect2, varscan2
- ANAPC7 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 70/224 reads (31%) | catalogued as COSV71443977; called by muse, mutect2, varscan2
- ARHGAP6 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV57304162; called by muse, mutect2, varscan2
- ASCL1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 116/260 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57152675; called by muse, mutect2, varscan2
- CCDC88C | c.2062G>A p.V688M | Missense Mutation (SNP) | VAF 112/272 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs375082540; called by muse, mutect2, varscan2
- CD163L1 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs1419039428; called by muse, mutect2, varscan2
- CD96 | c.1368A>T p.K456N (on ENST00000283285 / NM_198196.3; = p.K440N on NM_005816.5) | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV51912196; called by muse, mutect2, varscan2
- CHIC1 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773700231; called by muse, mutect2, varscan2
- CNTNAP5 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs762127739, COSV70472157; called by muse, mutect2, varscan2
- CREB3L4 | c.715_717del p.K239del | In Frame Del (DEL) | VAF 130/342 reads (38%) | catalogued as rs749320152; called by pindel, varscan2
- CSN1S2AP | n.334C>T | Splice Region (SNP) | VAF 86/209 reads (41%) | catalogued as rs1400455885; called by muse, mutect2, varscan2
- DKK2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs918911009; called by muse, mutect2, varscan2
- DLG2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as rs762841674, COSV54644952, COSV54680601; called by muse, mutect2, varscan2
- DLGAP3 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs146229611, COSV52395742; called by muse, mutect2, varscan2
- DOT1L | c.4411G>A p.G1471R | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1287116735; called by muse, mutect2, varscan2
- EPB41L4B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201249269, COSV65796261; called by muse, mutect2, varscan2
- ESYT1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as rs375034247; called by muse, mutect2, varscan2
- FBF1 | c.3049G>A p.E1017K (on ENST00000586717; = p.E1032K on NM_001319193.1) | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV59864366; called by muse, mutect2, varscan2
- FFAR3 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 285/978 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs760108323, COSV100588198; called by muse, mutect2, varscan2
- FLII | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 110/143 reads (77%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as rs992540301; called by muse, mutect2, varscan2
- GABRA1 | c.1057A>T p.K353* | Nonsense Mutation (SNP) | VAF 128/330 reads (39%) | catalogued as COSV50098684; called by muse, mutect2, varscan2
- GABRD | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as rs759836961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRASP2 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs763037008, COSV59990957; called by muse, mutect2
- H6PD | c.627+1G>A p.X209_splice | Splice Site (SNP) | VAF 113/335 reads (34%) | catalogued as COSV66230943; called by muse, mutect2, varscan2
- ITGBL1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV66005482; called by muse, mutect2, varscan2
- JPH2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs1475379949, COSV65905469; called by muse, mutect2, varscan2
- KCNQ5 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs751287194; called by muse, varscan2
- KIF26A | c.5453G>A p.R1818H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs374991880; called by muse, mutect2, varscan2
- KLHDC7A | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1215891451; called by muse, mutect2, varscan2
- KRTAP4-4 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 327/602 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV66811193; called by muse, varscan2
- L3MBTL3 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs760981827; called by muse, mutect2, varscan2
- MAGEA1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as rs1556944256, COSV100756626; called by muse, mutect2, varscan2
- MAGEB1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs754534422, COSV66775762; called by muse, mutect2, varscan2
- MYO1B | c.1895A>G p.Y632C | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1376559272; called by muse, mutect2, varscan2
- NAP1L3 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 101/292 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100220241; called by muse, mutect2, varscan2
- NIPBL | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 162/374 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.511); catalogued as rs748268539, COSV56952821; called by muse, mutect2, varscan2
- NPFFR1 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104375562; called by muse, varscan2
- NRROS | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs530581190, COSV60745744; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- OR5T3 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1406535307; called by muse, mutect2, varscan2
- P3H3 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 134/337 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs782559488; called by muse, mutect2, varscan2
- PCDH11X | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 214/496 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1462765032, COSV53441765; called by muse, mutect2, varscan2
- PDE1C | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187542698, COSV58503940, COSV58517817; called by muse, mutect2, varscan2
- PGBD2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 142/355 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV100252279; called by muse, mutect2, varscan2
- POT1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1186225134, COSV62933692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP4R2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs890569323; called by muse, mutect2, varscan2
- R3HCC1 | c.409C>T p.P137S (on ENST00000411463; = p.P97S on NM_001136108.3) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs781769852; called by muse, mutect2, varscan2
- RYR2 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs376135032; called by muse, mutect2, varscan2
- SAMD9L | c.3320G>A p.R1107H | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369116471; called by muse, mutect2, varscan2
- TFAP2A | c.362C>T p.S121L (on ENST00000482890; = p.S113L on NM_001032280.3) | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1161927231; called by muse, mutect2, varscan2
- TP53 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 119/156 reads (76%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as CD156964, COSV52711846, COSV52730924, COSV53119766; called by muse, mutect2, varscan2
- TTC28 | c.6136C>T p.R2046C | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.17); catalogued as rs1425935441; called by muse, mutect2, varscan2
- TTC4 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 134/343 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs764915602; called by muse, mutect2, varscan2
- VPS13B | c.10757G>A p.R3586Q | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs549125520, COSV100661420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC004922.1 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 7/197 reads (4%) | called by muse, mutect2
- ADD1 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGAP6 | c.1563G>A p.W521* (on ENST00000374056 / NM_001365867.1; = p.W544* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 36/517 reads (7%) | called by muse, mutect2
- ANHX | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD65 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC5 | c.2434G>A p.G812R | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BAZ1B | c.2867G>A p.S956N | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf167 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CCDC190 | c.583T>G p.S195A | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2
- CCNI | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- CCNT2 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CD36 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CNNM3 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COX10 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 110/157 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CTTNBP2 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 36/1342 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.429); called by muse, mutect2
- CUEDC1 | c.785-1G>A p.X262_splice | Splice Site (SNP) | VAF 104/363 reads (29%) | called by muse, mutect2, varscan2
- DCAF5 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DCTPP1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DECR2 | c.462+5G>A | Splice Region (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- DMRT1 | c.540G>A p.E180= | Splice Region (SNP) | VAF 114/313 reads (36%) | called by muse, mutect2, varscan2
- DNAJB6 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DNAJC7 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECE1 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT14 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2
- GKAP1 | c.820A>T p.N274Y | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- GLI3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 151/380 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ITGA10 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITIH6 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRT79 | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 183/438 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KXD1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPK1 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP25 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- MSH3 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 143/371 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYCBP2 | c.6415G>A p.D2139N (on ENST00000357337; = p.D2177N on NM_015057.5) | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NAF1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP8 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10G8 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR8J1 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL6 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 57/149 reads (38%) | called by muse, mutect2, varscan2
- PAK4 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.26); called by muse, varscan2
- PCDHA8 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 191/464 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCDHGB5 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHTF2 | c.753G>A p.W251* (on ENST00000248550 / NM_001366089.1; = p.W213* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 103/435 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PLCH1 | c.434+1A>G p.X145_splice (on ENST00000340059 / NM_001130960.2; = p.X157_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 68/165 reads (41%) | called by muse, mutect2, varscan2
- PLOD3 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- POM121C | c.1141G>A p.G381S (on ENST00000607367; = p.G139S on NM_001099415.3) | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PPP1R18 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 147/398 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PROKR2 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PTGER4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- RAP1GAP | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ROBO3 | c.3770C>T p.P1257L | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC10A5 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SLC39A6 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA5 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- SNX13 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SPTAN1 | c.6091dup p.E2031Gfs*78 | Frame Shift Ins (INS) | VAF 228/611 reads (37%) | called by mutect2, pindel, varscan2
- STAMBPL1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TASOR2 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 95/125 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFE3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.55634C>T p.P18545L (on ENST00000591111; = p.P11121L on NM_003319.4) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- WHRN | c.837G>A p.K279= | Splice Region (SNP) | VAF 84/199 reads (42%) | called by muse, mutect2, varscan2
- ZBTB9 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMYM6 | c.2578A>T p.M860L | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF100 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ZNF281 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 160/466 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADGRF1 | c.2395C>T p.L799= | Silent (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- ANKRD34C | c.339C>T p.S113= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- AOC2 | c.705C>T p.H235= | Silent (SNP) | VAF 78/279 reads (28%) | catalogued as rs1203062275; called by muse, mutect2, varscan2
- ASCL1 | c.585C>T p.P195= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- ATXN1 | c.970C>T p.L324= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- AVIL | c.1368A>G p.S456= | Silent (SNP) | VAF 214/514 reads (42%) | called by muse, mutect2, varscan2
- AVPR1A | c.441C>T p.A147= | Silent (SNP) | VAF 102/243 reads (42%) | catalogued as rs768124807; called by muse, mutect2, varscan2
- BAG1 | c.147C>T p.A49= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs760236330; called by muse, mutect2, varscan2
- BANP | c.831G>A p.G277= (on ENST00000286122; = p.G246= on NM_017869.4) | Silent (SNP) | VAF 80/208 reads (38%) | catalogued as rs1289892623; called by muse, mutect2, varscan2
- CCL4 | c.120G>A p.A40= | Silent (SNP) | VAF 133/543 reads (24%) | catalogued as rs774792725; called by muse, mutect2, varscan2
- CEACAM5 | c.1854C>T p.A618= | Silent (SNP) | VAF 148/387 reads (38%) | called by muse, mutect2, varscan2
- CILP2 | c.294G>A p.A98= | Silent (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- CSMD2 | c.3852G>A p.L1284= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as rs781417020; called by muse, mutect2, varscan2
- DES | c.1326C>T p.T442= | Silent (SNP) | VAF 136/363 reads (37%) | catalogued as COSV64660170; called by muse, mutect2, varscan2
- FAM102A | c.54G>A p.L18= | Silent (SNP) | VAF 72/177 reads (41%) | called by muse, mutect2, varscan2
- FAM149A | c.120G>A p.G40= | Silent (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- FHDC1 | c.2193C>T p.A731= | Silent (SNP) | VAF 69/186 reads (37%) | called by muse, mutect2, varscan2
- GBA3 | c.819C>T p.A273= | Silent (SNP) | VAF 104/265 reads (39%) | called by muse, mutect2, varscan2
- GCN1 | c.4218G>A p.K1406= | Silent (SNP) | VAF 124/326 reads (38%) | called by muse, mutect2
- GOLGA8S | c.585G>A p.A195= | Silent (SNP) | VAF 99/335 reads (30%) | catalogued as rs772756960; called by muse, mutect2, varscan2
- GPRASP2 | c.1266G>A p.A422= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as rs751801676, COSV59992381; called by muse, mutect2
- HECW1 | c.2172C>T p.S724= | Silent (SNP) | VAF 63/151 reads (42%) | catalogued as COSV67822025; called by muse, mutect2, varscan2
- IL16 | c.1995C>T p.I665= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as rs372001575; called by muse, mutect2, varscan2
- ITGA5 | c.2370C>T p.A790= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as rs764438371; called by muse, mutect2, varscan2
- ITPR2 | c.1284G>A p.A428= | Silent (SNP) | VAF 59/98 reads (60%) | catalogued as rs199897476; called by muse, mutect2, varscan2
- KCNK9 | c.699G>C p.T233= | Silent (SNP) | VAF 109/277 reads (39%) | catalogued as rs201576708, COSV57288026; called by muse, mutect2, varscan2
- LONRF2 | c.1602G>A p.L534= | Silent (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- LRRC49 | c.12G>A p.G4= | Silent (SNP) | VAF 105/292 reads (36%) | catalogued as rs1040798295; called by muse, mutect2, varscan2
- MGAT5B | c.1341C>T p.N447= | Silent (SNP) | VAF 207/352 reads (59%) | catalogued as rs754477097, COSV56926540; called by muse, mutect2, varscan2
- OCRL | c.2674C>T p.L892= | Silent (SNP) | VAF 202/517 reads (39%) | catalogued as rs1233884460, COSV100843409; called by muse, mutect2, varscan2
- PDE11A | c.1401C>T p.S467= | Silent (SNP) | VAF 190/442 reads (43%) | catalogued as rs754452312; called by muse, mutect2, varscan2
- PGK2 | c.375T>C p.H125= | Silent (SNP) | VAF 77/175 reads (44%) | catalogued as rs1194218791, COSV59165368; called by muse, mutect2, varscan2
- PHGDH | c.1135C>T p.L379= | Silent (SNP) | VAF 173/439 reads (39%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.1104C>T p.N368= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs28610486; called by mutect2, varscan2
- RIPK4 | c.1689G>T p.G563= (on ENST00000352483; = p.G515= on NM_020639.3) | Silent (SNP) | VAF 98/267 reads (37%) | catalogued as COSV100205441; called by muse, mutect2
- SCLT1 | c.1249C>A p.R417= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as COSV55413156; called by muse, mutect2, varscan2
- SLC44A2 | c.1158C>T p.S386= | Silent (SNP) | VAF 106/285 reads (37%) | catalogued as rs1025215369; called by muse, mutect2, varscan2
- SLIT3 | c.1236C>T p.D412= | Silent (SNP) | VAF 66/189 reads (35%) | called by muse, mutect2, varscan2
- SORCS3 | c.165G>C p.A55= | Silent (SNP) | VAF 74/88 reads (84%) | called by muse, mutect2, varscan2
- SPTBN1 | c.4110G>A p.Q1370= | Silent (SNP) | VAF 78/202 reads (39%) | called by muse, mutect2, varscan2
- SYNGR1 | c.261C>T p.A87= | Silent (SNP) | VAF 167/351 reads (48%) | called by muse, mutect2, varscan2
- TFR2 | c.744C>T p.A248= | Silent (SNP) | VAF 105/486 reads (22%) | catalogued as rs1160583358; called by muse, mutect2, varscan2
- TIAM2 | c.435G>A p.E145= | Silent (SNP) | VAF 122/339 reads (36%) | called by muse, mutect2, varscan2
- TRIM33 | c.1812G>A p.R604= | Silent (SNP) | VAF 69/138 reads (50%) | catalogued as COSV61822460; called by muse, mutect2, varscan2
- TTI1 | c.969A>G p.Q323= | Silent (SNP) | VAF 147/337 reads (44%) | catalogued as rs193227299; called by muse, mutect2, varscan2
- ZFP64 | c.1857C>T p.A619= | Silent (SNP) | VAF 145/383 reads (38%) | called by muse, mutect2, varscan2
- ZNF711 | c.609C>T p.Y203= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV52152826, COSV99341757; called by muse, mutect2
- ADAM1A | chr12:111901444 G>A | 3'Flank (SNP) | VAF 77/194 reads (40%) | catalogued as rs968926974; called by muse, mutect2, varscan2
- AP4S1 | c.294+58G>A | Intron (SNP) | VAF 96/239 reads (40%) | called by muse, mutect2, varscan2
- C16orf86 | c.103-52C>T | Intron (SNP) | VAF 133/381 reads (35%) | catalogued as rs1416891570; called by muse, mutect2, varscan2
- CHRND | c.*670C>T | 3'UTR (SNP) | VAF 24/574 reads (4%) | called by muse, mutect2
- CSTF2 | c.890-673G>T | Intron (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- EVPL | c.1537+20G>A | Intron (SNP) | VAF 14/165 reads (8%) | catalogued as rs773773376; called by muse, mutect2
- ISM2 | c.141+328C>T | Intron (SNP) | VAF 48/57 reads (84%) | called by muse, mutect2, varscan2
- LAMA1 | c.1156-38T>A | Intron (SNP) | VAF 90/196 reads (46%) | called by muse, mutect2, varscan2
- LINC01193 | n.1463G>A | RNA (SNP) | VAF 107/274 reads (39%) | catalogued as rs747466190; called by muse, mutect2, varscan2
- MAMLD1 | c.2285-37G>T | Intron (SNP) | VAF 71/195 reads (36%) | called by muse, mutect2, varscan2
- MAMLD1 | c.2285-36C>T | Intron (SNP) | VAF 71/194 reads (37%) | catalogued as rs1557409043; called by muse, mutect2, varscan2
- MAN1B1 | c.*198G>A | 3'UTR (SNP) | VAF 19/532 reads (4%) | called by muse, mutect2
- MAP4K2 | c.1170+17G>A | Intron (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- MTFR1L | c.-62C>T | 5'UTR (SNP) | VAF 90/241 reads (37%) | catalogued as rs1255449693; called by muse, mutect2, varscan2
- ODF3 | c.311-90C>T | Intron (SNP) | VAF 71/192 reads (37%) | called by muse, mutect2, varscan2
- RNF145 | c.-40+1460G>A | Intron (SNP) | VAF 115/315 reads (37%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3703G>A | RNA (SNP) | VAF 56/154 reads (36%) | catalogued as rs1376706655; called by muse, mutect2, varscan2
- SMARCB1 | c.490+28C>T | Intron (SNP) | VAF 149/377 reads (40%) | called by muse, mutect2, varscan2
- TAMM41 | c.136-708C>A | Intron (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- TTC4 | c.111+51G>A | Intron (SNP) | VAF 28/65 reads (43%) | catalogued as COSV100988488; called by muse, mutect2
